Somatic mutation profile of tumor specimen TCGA-CQ-A4CG-01A (aliquot TCGA-CQ-A4CG-01A-11D-A25Y-08) from TCGA case TCGA-CQ-A4CG, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 78.4 years (28,637 days).
Specimen TCGA-CQ-A4CG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b557161a-ce68-41c2-96ec-22f382e45b94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-A4CG-10A (Blood Derived Normal), aliquot TCGA-CQ-A4CG-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3036a902-894b-4c70-8984-8297d020552c

The open-access MAF lists 89 somatic variants for this specimen: 65 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, RNA 3, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HRAS | c.351G>T p.K117N | Missense Mutation (SNP) | VAF 77/212 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV54236714, COSV54237107; called by muse, mutect2, varscan2
- NFE2L2 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 39/52 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328994103, COSV67960091, COSV67960815, COSV67963035; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 61/96 reads (64%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA6 | c.2395G>T p.E799* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs771243934, COSV52641606, COSV99447676; called by muse, mutect2
- ABCC11 | c.1959G>T p.Q653H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV62323493, COSV62323988; called by muse, mutect2, varscan2
- AC068580.4 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99362503, COSV99362545; called by muse, mutect2, varscan2
- ADNP2 | c.1772C>A p.T591N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV100081196; called by muse, mutect2, varscan2
- AKAP14 | c.248A>C p.D83A | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV100538408; called by muse, mutect2, varscan2
- ALDH1A2 | c.1438C>A p.Q480K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99991093; called by muse, mutect2, varscan2
- APC2 | c.2650C>T p.P884S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.018); catalogued as rs757008559, COSV99279861; called by muse, varscan2
- APLP1 | c.920A>C p.H307P | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99697928; called by muse, mutect2, varscan2
- ATP7B | c.2491G>A p.V831I | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs374592960; called by muse, mutect2, varscan2
- BACH1 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1295914538, COSV99728682; called by muse, mutect2, varscan2
- BDKRB1 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99388033; called by muse, mutect2, varscan2
- CDYL2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs763202229, COSV101629622; called by muse, mutect2, varscan2
- CHM | c.383C>A p.A128E | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100753636; called by muse, mutect2, varscan2
- CNTNAP5 | c.1638C>G p.I546M | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs774515049, COSV101444202, COSV70483811; called by muse, mutect2, varscan2
- CR2 | c.2561C>T p.P854L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772503117, COSV65505978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISP3 | c.578A>C p.Q193P | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs758324328, COSV99609935; called by muse, mutect2, varscan2
- DMD | c.2440G>A p.E814K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.15); catalogued as rs1408435603, CM098386, COSV100822695; called by muse, mutect2, varscan2
- DNAH1 | c.8014G>A p.A2672T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV101324963; called by muse, mutect2, varscan2
- DOCK11 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs200968541, COSV52236600; called by muse, mutect2, varscan2
- ESYT1 | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99920284; called by muse, mutect2, varscan2
- EVA1C | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV100291589; called by muse, mutect2, varscan2
- GP1BA | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.839); catalogued as rs755192403, COSV56699895; called by muse, mutect2, varscan2
- GPAM | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368640883, COSV62082043; called by muse, mutect2
- HSPB2 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 87/364 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99909974; called by muse, mutect2, varscan2
- ICAM1 | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV99321141; called by muse, mutect2, varscan2
- JPH3 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780773717, COSV52465346; called by muse, mutect2, varscan2
- KBTBD3 | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101595729; called by muse, mutect2, varscan2
- KCNQ2 | c.845A>G p.D282G | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV100610543; called by muse, mutect2, varscan2
- KCTD12 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV100499754, COSV58524920; called by muse, mutect2, varscan2
- KIF21B | c.3764G>A p.R1255H | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100145127; called by muse, mutect2, varscan2
- KIRREL2 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs376544628, COSV52877753; called by muse, mutect2, varscan2
- KLHL26 | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1433349128, COSV99963369; called by muse, mutect2
- LRFN5 | c.1726G>C p.A576P | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as COSV53268608, COSV99985416; called by muse, mutect2, varscan2
- LRP1B | c.6427G>T p.G2143W | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101253520, COSV101260818; called by muse, mutect2, varscan2
- LRTM2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747004809, COSV54565773; called by muse, mutect2, varscan2
- MEF2C | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100426203; called by muse, mutect2, varscan2
- NLRP8 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.177); catalogued as rs759351908, COSV52585627; called by muse, mutect2, varscan2
- NOTCH3 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99658772; called by muse, mutect2, varscan2
- OR4D5 | c.419T>A p.V140D | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV100190181; called by muse, mutect2, varscan2
- PCLO | c.3772G>A p.E1258K | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.453); catalogued as COSV61652778; called by muse, mutect2, varscan2
- PPFIA4 | c.3434C>T p.P1145L (on ENST00000447715; = p.P1146L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1429089497, COSV99690945; called by muse, mutect2, varscan2
- PRB1 | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV99556040; called by muse, mutect2, varscan2
- PROM1 | c.1675G>T p.V559F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV101477132; called by muse, mutect2, varscan2
- SFTPD | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as rs142564545; ClinVar: likely benign; called by muse, mutect2, varscan2
- SI | c.1001T>C p.V334A | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1173323197, COSV52281551; called by muse, varscan2
- SLC16A1 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100856076; called by muse, mutect2, varscan2
- SLC24A2 | c.1228+1G>A p.X410_splice | Splice Site (SNP) | VAF 22/52 reads (42%) | catalogued as rs1423245449, COSV99647435; called by muse, mutect2, varscan2
- SLC9B2 | c.1396G>T p.A466S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757350652, COSV100294336; called by muse, mutect2, varscan2
- SPEM2 | c.1228G>C p.A410P | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.682); catalogued as COSV100424497; called by muse, mutect2, varscan2
- TBL1X | c.728T>G p.V243G | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.143); catalogued as COSV99483142; called by muse, mutect2, varscan2
- TMTC2 | c.692T>A p.L231* | Nonsense Mutation (SNP) | VAF 48/126 reads (38%) | catalogued as COSV100338834, COSV58284013; called by muse, mutect2, varscan2
- UBE3B | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs369410122; called by muse, mutect2, varscan2
- WIPF2 | c.53C>T p.T18I | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100063922; called by muse, mutect2, varscan2
- ZNF420 | c.495A>C p.K165N | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100421507, COSV58494741; called by muse, mutect2, varscan2
- ZNF449 | c.419C>A p.T140N | Missense Mutation (SNP) | VAF 66/218 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100203066; called by muse, mutect2, varscan2
- ZNF667 | c.843T>G p.H281Q | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV99410959; called by muse, mutect2, varscan2
- DGAT2L6 | c.325dup p.H109Pfs*15 | Frame Shift Ins (INS) | VAF 18/87 reads (21%) | called by pindel, varscan2
- DGAT2L6 | c.326A>C p.H109P | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FAT1 | c.2828dup p.T944Nfs*12 | Frame Shift Ins (INS) | VAF 83/242 reads (34%) | called by mutect2, pindel, varscan2
- ZBTB22 | c.1657del p.R553Efs*160 | Frame Shift Del (DEL) | VAF 48/147 reads (33%) | called by mutect2, pindel, varscan2
- ZNF648 | c.777T>A p.F259L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2
- CCDC88C | c.4956C>G p.A1652= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100485050; called by muse, mutect2, varscan2
- CSMD3 | c.9786C>G p.G3262= (on ENST00000297405 / NM_001363185.1; = p.G3093= on NM_052900.3) | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV52208143, COSV99847237; called by muse, mutect2, varscan2
- CTH | c.438A>G p.A146= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100697154; called by muse, mutect2, varscan2
- CYP2A6 | c.387C>T p.R129= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV99992165; called by muse, mutect2, varscan2
- FAM126A | c.1380C>T p.V460= | Silent (SNP) | VAF 33/114 reads (29%) | catalogued as COSV101327264; called by muse, mutect2, varscan2
- GDF5 | c.996C>T p.A332= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as rs1198479678, COSV100976972; called by muse, mutect2, varscan2
- KALRN | c.3054C>G p.V1018= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1361537060, COSV99567223; called by muse, mutect2, varscan2
- LILRB3 | c.9C>T p.P3= | Silent (SNP) | VAF 24/205 reads (12%) | catalogued as rs566409321, COSV54427816; called by muse, mutect2, varscan2
- NCOA6 | c.2487C>T p.V829= | Silent (SNP) | VAF 140/260 reads (54%) | catalogued as rs761374604, COSV100750343, COSV100750406; called by muse, mutect2, varscan2
- NCOR2 | c.3951C>A p.R1317= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV100656725, COSV100657875; called by muse, mutect2, varscan2
- OR10G8 | c.195G>C p.S65= | Silent (SNP) | VAF 121/210 reads (58%) | catalogued as rs140497683, COSV70908367, COSV70909159; called by muse, mutect2, varscan2
- PAMR1 | c.2004C>T p.I668= (on ENST00000619888 / NM_001001991.3; = p.I685= on NM_015430.4) | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as rs1385673358, COSV53510802; called by muse, mutect2, varscan2
- RAVER1 | c.1710C>A p.A570= (on ENST00000615032; = p.Q697K on NM_133452.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99533138; called by muse, mutect2, varscan2
- RRP1 | c.696C>T p.L232= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV101513891; called by muse, mutect2, varscan2
- SLC7A1 | c.213G>T p.L71= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV101060290, COSV66330960; called by muse, mutect2, varscan2
- SORCS3 | c.876G>T p.R292= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV100865649, COSV63826086; called by muse, mutect2, varscan2
- SPAG6 | c.1110C>T p.H370= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs767182864, COSV57624286; called by muse, mutect2, varscan2
- SPTBN5 | c.1963C>T p.L655= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV58021914; called by muse, mutect2, varscan2
- SYCN | c.105G>A p.T35= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV59213047; called by muse, mutect2, varscan2
- WFIKKN1 | c.246C>A p.G82= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99937992; called by muse, mutect2, varscan2
- C9orf129 | n.571C>T | RNA (SNP) | VAF 24/105 reads (23%) | catalogued as COSV100962526; called by muse, mutect2, varscan2
- CDKL1 | n.157G>A | RNA (SNP) | VAF 116/214 reads (54%) | called by muse, mutect2, varscan2
- PVRIG | chr7:100223922 G>A | 3'Flank (SNP) | VAF 41/132 reads (31%) | catalogued as COSV52782625; called by muse, mutect2, varscan2
- SSPOP | n.11899C>G | RNA (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100948022, COSV65131517; called by muse, mutect2
